Somatic mutation profile of tumor specimen TCGA-BG-A0MK-01A (aliquot TCGA-BG-A0MK-01A-51D-A19Y-09) from TCGA case TCGA-BG-A0MK, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 52.1 years (19,034 days).
Specimen TCGA-BG-A0MK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e7a7b67-b00c-4010-8fae-1e0498e8e79d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BG-A0MK-10A (Blood Derived Normal), aliquot TCGA-BG-A0MK-10A-01D-A19Y-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc1feda3-86a4-4ff4-80e3-3d61d0ce49e5

The open-access MAF lists 69 somatic variants for this specimen: 50 protein-altering or splice-affecting, 19 silent.
By variant classification: Missense Mutation 44, Silent 19, Nonsense Mutation 3, Splice Region 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTCF | c.1342C>T p.R448* | Nonsense Mutation (SNP) | VAF 12/27 reads (44%) | hotspot (GDC flag); catalogued as rs769948988, COSV50461776; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 23/31 reads (74%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.246A>T p.E82D | Missense Mutation (SNP) | VAF 50/123 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67960116, COSV67960221; called by muse, mutect2, varscan2
- PIK3CA | c.1636C>G p.Q546E | Missense Mutation (SNP) | VAF 26/57 reads (46%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen benign (0.264); catalogued as rs121913286, COSV55873527, COSV55882350; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.1026+1G>A p.X342_splice | Splice Site (SNP) | VAF 27/38 reads (71%) | hotspot (GDC flag); catalogued as rs786201041, CS043794, CS110216, COSV64288702, COSV64289135, COSV64293873; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATXN2 | c.3246del p.H1082Qfs*6 (on ENST00000550104; = p.H922Qfs*6 on NM_002973.4) | Frame Shift Del (DEL) | VAF 4/37 reads (11%) | catalogued as COSV66481369; called by mutect2, pindel, varscan2
- CACNB4 | c.109G>T p.D37Y | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.848); catalogued as COSV99137835; called by muse, mutect2, varscan2
- CLK1 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.394); catalogued as COSV100362148; called by muse, mutect2, varscan2
- COL11A1 | c.4406A>G p.E1469G | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100615378, COSV62171557; called by muse, mutect2
- CORO7 | c.2245G>A p.G749S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs746919528, COSV99227253; called by muse, mutect2, varscan2
- CRACR2B | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs200216625, COSV100351957; called by muse, mutect2, varscan2
- DOCK10 | c.2158C>G p.P720A | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99287918; called by muse, mutect2, varscan2
- DOCK3 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs1325377187, COSV56530671; called by muse, mutect2, varscan2
- ELL3 | c.1187G>A p.G396D | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV55857033; called by muse, mutect2, varscan2
- FKBP6 | c.502C>A p.L168M | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.421); catalogued as COSV99333745; called by muse, mutect2
- GIT1 | c.1802C>T p.T601M | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs775716001, COSV99837911; called by muse, mutect2, varscan2
- GUF1 | c.1732A>G p.I578V | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs150660496; called by muse, mutect2, varscan2
- HSPG2 | c.354G>A p.T118= | Splice Region (SNP) | VAF 4/40 reads (10%) | catalogued as COSV65930888; called by muse, mutect2, varscan2
- IGHD | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.262); catalogued as rs775413628, COSV101162807; called by muse, mutect2
- IGLON5 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1215338716, COSV99570479; called by muse, mutect2, varscan2
- INSL4 | c.212C>T p.S71F | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0.339); catalogued as COSV99497077; called by muse, mutect2, varscan2
- KMT2A | c.11881G>T p.A3961S | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as rs781866935, COSV100628110, COSV63294851; called by muse, mutect2
- LHX5 | c.497C>T p.T166M | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.715); catalogued as rs1285111455, COSV99922396; called by muse, mutect2
- LLGL2 | c.724G>A p.G242S | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.171); catalogued as rs763984358, COSV51419651; called by muse, mutect2, varscan2
- LRBA | c.6817A>G p.I2273V | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs750883073, COSV100841015; called by muse, mutect2
- MTFR1 | c.46G>C p.V16L | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.102); catalogued as COSV100050035; called by muse, mutect2, varscan2
- MYO5C | c.1469A>G p.N490S | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99954198; called by muse, mutect2, varscan2
- NBEA | c.6205G>T p.D2069Y | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100077266; called by muse, mutect2, varscan2
- NCOA5 | c.861G>A p.M287I | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.129); catalogued as COSV99275264; called by muse, mutect2, varscan2
- NEBL | c.2003G>A p.S668N | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as COSV101009111; called by muse, mutect2
- NUDT10 | c.331G>A p.V111I | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100726785; called by muse, mutect2
- OBSCN | c.8798C>T p.A2933V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.401); catalogued as rs1401504892, COSV99473836; called by muse, mutect2
- OGN | c.832G>A p.V278I | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs758663034, COSV99363986; called by mutect2, varscan2
- RPAIN | c.464A>G p.Q155R | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.069); catalogued as COSV100506761; called by muse, mutect2
- SACM1L | c.188C>T p.T63I | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.65); PolyPhen benign (0.048); catalogued as rs1359401221, COSV101203749; called by muse, mutect2, varscan2
- SCN1A | c.3892A>C p.S1298R (on ENST00000303395 / NM_001202435.3; = p.S1287R on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV57663885; called by muse, mutect2, varscan2
- SLC17A6 | c.466G>T p.G156* | Nonsense Mutation (SNP) | VAF 6/88 reads (7%) | catalogued as COSV54139647, COSV99580881; called by muse, mutect2
- SLC30A10 | c.1177C>T p.Q393* | Nonsense Mutation (SNP) | VAF 31/63 reads (49%) | catalogued as COSV100751438; called by muse, mutect2, varscan2
- SLC5A11 | c.1564C>A p.L522I | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100762690; called by muse, mutect2
- SLITRK2 | c.2386G>T p.D796Y | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV100157389; called by muse, mutect2, varscan2
- SPEN | c.1627G>A p.V543M | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101005021; called by muse, mutect2
- SYNJ1 | c.1175C>A p.P392H | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100448990; called by muse, mutect2, varscan2
- TRERF1 | c.1997C>T p.P666L | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs928875702, COSV61670535; called by muse, mutect2
- TULP4 | c.3296A>G p.Q1099R | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.007); catalogued as rs867792725, COSV100893198; called by muse, varscan2
- TUT7 | c.1163A>G p.D388G | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99462507; called by muse, mutect2, varscan2
- UBAC1 | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.2); catalogued as rs763247432, COSV100873756; called by muse, mutect2, varscan2
- WDR82 | c.269G>C p.R90P | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99626614; called by muse, mutect2, varscan2
- YTHDF3 | c.220G>C p.A74P | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV101572358; called by muse, mutect2
- ZSCAN10 | c.1600C>T p.R534C (on ENST00000252463; = p.R589C on NM_032805.3) | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1017863494, COSV52971419; called by muse, mutect2, varscan2
- IZUMO1R | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ARHGEF15 | c.1545G>A p.Q515= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV100729990; called by muse, mutect2, varscan2
- CDX4 | c.342C>T p.S114= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV100999109; called by muse, mutect2, varscan2
- ENOSF1 | c.825C>A p.L275= (on ENST00000340116 / NM_001354066.2; = p.L227= on NM_017512.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as COSV99200975; called by mutect2, varscan2
- FAM193B | c.768G>A p.P256= | Silent (SNP) | VAF 42/126 reads (33%) | catalogued as rs552535575, COSV100286417; called by muse, mutect2, varscan2
- FAM91A1 | c.2055C>T p.G685= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV100593452; called by muse, mutect2
- KCNC1 | c.297C>T p.T99= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV99788829; called by muse, mutect2, varscan2
- LRIG1 | c.2361G>A p.R787= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV99833134; called by muse, mutect2, varscan2
- NPAP1 | c.918G>A p.K306= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as COSV100274860; called by muse, mutect2, varscan2
- PHF8 | c.141G>T p.R47= (on ENST00000357988 / NM_001184896.1; = p.R11= on NM_015107.3) | Silent (SNP) | VAF 25/72 reads (35%) | catalogued as COSV100153863; called by muse, mutect2, varscan2
- RASGRP4 | c.1776G>A p.K592= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as COSV99384847; called by muse, mutect2, varscan2
- SCN4A | c.5277C>T p.D1759= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as rs548333586, COSV71127963; ClinVar: likely benign; called by muse, mutect2, varscan2
- STX3 | c.78C>T p.I26= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as rs376688869; called by muse, mutect2, varscan2
- SYNE1 | c.23982C>T p.I7994= (on ENST00000367255 / NM_182961.4; = p.I7923= on NM_033071.3) | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs746166486, COSV99552310; called by muse, varscan2
- SYT16 | c.690G>A p.S230= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as rs368163995; called by muse, mutect2, varscan2
- SYT6 | c.411G>A p.T137= (on ENST00000610222 / NM_001366225.1; = p.T52= on NM_205848.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs536926240, COSV101059611; called by muse, mutect2, varscan2
- TTC17 | c.2124A>G p.A708= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV99234775; called by muse, mutect2, varscan2
- TUBB2B | c.1116G>A p.T372= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV52534339; called by muse, varscan2
- UNC5B | c.1878C>T p.A626= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs145578164; called by muse, mutect2, varscan2
- VPS11 | c.489C>T p.S163= (on ENST00000620429; = p.S707= on NM_021729.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs782272810, COSV100333567; called by mutect2, varscan2
